Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94I, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Barretos Cancer Hospital, specimen TCGA-YU-A94I-01A (Primary Tumor).

ICD-O-3
Yolk sac tumor 9071/3
Site D Testis NOS C62.9
3/3/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

1-"Left testis":

- Yolk sac tumor (95%) with foci of embryonal carcinoma associated (5%).
- Neoplasia size: 8.5 x 7.0 x 6.0cm.
- Presence of extensive necrotic areas and intense desmoplasia.
- Perineural invasion not detected.
- Angiolymphatic invasion not detected.
- Tunica albuginea: uninvolved by neoplasia.
- Spermatic cord and epididymis uninvolved by neoplasia.
- Testicular parenchyma exhibiting moderate atrophy.
- Margin of spermatic cord uninvolved by neoplasia.
-

Note: see immunohistochemical study.

PATHOLOGIC STAGING

Topography	Morphology	Stage
Testis, NOS	Yolk sac tumor	pT1

Criteria	W 11/18/13	Yes	No

Source: NCI Genomic Data Commons file 5ea8868b-8965-43ea-948f-088e050d401c (TCGA-YU-A94I.60DF6F2B-1E0C-4258-97A5-F3954F4D76BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).